Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA1O, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA1O-06A (Metastatic).

[page 1 of 2]
ICD0-3

Melanoma NOS 8720/3
Site Lymph nodes, axilla C77.3
Jc 4/2/14

CLINICAL HISTORY

Metastatic melanoma, right axilla; unknown primary.

GROSS DESCRIPTION

1. Labeled "pigmented lesion, right posterior shoulder": The specimen consists of a tan skin ellipse. Short stitch marking anterior and long stitch marking lateral aspect are noted. The anterior aspect will be designated 12 o'clock and the lateral aspect 3 o'clock.

The specimen measures 5.5 (12 to 6 o'clock) by 2.0 (3 to 9 o'clock) by 0.9 cm. The 3 o'clock aspect is marked with black ink and the 9 o'clock aspect with blue ink. Centrally

there is an irregularly shaped unevenly pigmented lesion which measures 1.2 (3 to 9 o'clock) by 1.2 (12 to 6 o'clock dimension). The specimen is serially embedded from

anterior to posterior in cassettes A through E.

2. Labeled "right axillary contents": The specimen consists of a fat pad which measures

18 x 1.25 x 4.0 cm. At one end of the specimen there is a tan skin ellipse which measures

10.2 x 3.5 cm. It has a recently sutured longitudinal incision which measures 6.5 cm in

length. At the opposite end of the specimen there is a stitch marking highest axillary

node. The undersurface is fascia with some tags of skeletal muscle. Deep aspect has been

previously incised revealing a previously bisected tan tumorous nodule which measures 1.8

cm in greatest dimension. Contiguous with this nodule is a multinodular matted tumorous

mass which measures 1.5 cm in greatest dimension. Sectioning deep to the skin ellipse

reveals an indurated poorly defined area which varies in color from tan to yellow to red

and measures 4.0 x 2.5 x 3.0 cm. It abuts the deep aspect of the specimen.

Representative

sections submitted as follows: 2A - skin, 2B - incised nodule, 2C-D - multinodular mass

contiguous with incised nodule, 2E-2F - biopsy site, 2G - cassette consists of five single

lymph nodes, 2H - three bisected lymph nodes, 2I - two bisected lymph nodes, 2J - half of

one bisected lymph node, 2K - half of one bisected lymph node, 2L - one large bisected

lymph node, 2M - six single lymph nodes, 2N - eight single lymph nodes, 2O - six single

lymph nodes, 2P - three bisected lymph nodes, 2Q - four single lymph nodes and one bisected

lymph node, 2R - three bisected lymph nodes.

[page 2 of 2]
Microscopic sections are prepared and interpreted.

COMMENT

Dr. XXXXXX has reviewed the pigmented lesion and agrees with the interpretation.

DIAGNOSIS

1. LABELED "PIGMENTED LESION RIGHT POSTERIOR SHOULDER".
- ATYPICAL JUNCTIONAL MELANOCYTIC HYPERPLASIA WITH RARE JUNCTIONAL NESTS, RARE BENIGN DERMAL NEVUS COMPONENT, AND PATCHY CHRONIC INFLAMMATION AND FIBROSIS.
- COULD REPRESENT RESIDUUM OF REGRESSED MELANOMA, HOWEVER, NO OVERT MELANOMA IS PRESENT.
- LESION IS COMPLETELY EXCISED.
- SEE COMMENT.
2. LABELED "RIGHT AXILLARY CONTENTS".
- INCLUDING TWELVE OF FORTY-EIGHT LYMPH NODES POSITIVE FOR METASTATIC MELANOMA GROSSLY DESCRIBED INCISED NODULE, 1.8 CM AND FIVE MATTED POSITIVE LYMPH NODES DESCRIBED AS MULTINODULAR MASS, 1.5 CM.
- SOFT TISSUE AND SKIN SHOWING BIOPSY REACTION.

signed Electronically signed by:

** END OF REPORT **

Criteria	hw 12/19/13	Yes	No
Reviewed Initials	hw	Date Reviewed:	12/19/13

Source: NCI Genomic Data Commons file d0773a62-d7d9-4860-9ace-19dfc143cda1 (TCGA-W3-AA1O.4D210AC6-A8D1-4AA0-8930-B98E81B5FC9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).